MMRF case MMRF_2141 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/be47e303-eb92-415d-b992-d59bbb6a2f8d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.0 years (22,645 days); ISS stage: II; Days to last known disease status: 892 days (2.4 years); Days to last follow up: 892 days (2.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 270 days; Days to treatment end: 270 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 2.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.741 mg/dL; Immunoglobulin G 29.8 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.65 g/L; Beta 2 Microglobulin 2.03 µg/mL; Hemoglobin 8.99 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 9.1 g/dL; Glucose 5.34 mmol/L.
- Day 88 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.973 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.71 g/L; Beta 2 Microglobulin 1.89 µg/mL; Hemoglobin 8.8 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 4.57 mmol/L.
- Day 143 (ECOG 1): Hemoglobin 8.99 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 291 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.67 mmol/L.
- Day 245 (ECOG 0): M Protein 0.72 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.67 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 6.93 mmol/L.
- Day 343 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.78 g/L; Beta 2 Microglobulin 2.42 µg/mL; Hemoglobin 7.94 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.5 mmol/L.
- Day 511 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.764 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 6.16 mmol/L.
- Day 548 (ECOG 0): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.656 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 1.92 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 3.91 mmol/L.
- Day 638 (ECOG 0): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.958 mg/dL; Beta 2 Microglobulin 1.85 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 5.94 mmol/L.
- Day 714 (ECOG 0): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 1.92 µg/mL; Hemoglobin 8.31 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 808 (ECOG 0): M Protein 0.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.878 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.59 g/L; Beta 2 Microglobulin 1.81 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.61 mmol/L.
- Day 892 (ECOG 1): M Protein 0.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.895 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.62 g/L; Beta 2 Microglobulin 1.54 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day 1: Weight: 48 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2141_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2141_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
